Gene-level copy-number profile of tumor specimen C3N-02588-01 (profiled together with C3N-02588-02) from CPTAC case C3N-02588, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.1 years (25,225 days).
Specimen C3N-02588-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c1b83122-8d0d-4b66-ab70-de4c1cd8cf8b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02588-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/2cbae423-49c2-4dcc-b3ac-e1fde44375df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 589; copy number 2: 27,853; copy number 3: 21,552; copy number 4: 7,705; copy number 5: 130; copy number 6: 876; copy number 7: 158; copy number 10: 2; copy number 12: 2; copy number 13: 8; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:212,824–1,333,953, 21 genes: DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279.
- chr9:9,090,898–9,091,245, 1 gene (within-gene range 0–3): RPS26P3.
- chr9:9,799,423–9,803,784, 1 gene (within-gene range 0–3): AL513422.1.
- chr12:47,972,967–48,106,079, 9 genes (within-gene range 0–2): COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2, RNU6-1203P, AC004801.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,176 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,736,726–91,767,439, 1 gene, copy number 6 (within-gene range 3–6): AC027612.1.
- chr2:91,759,462–91,781,169, 2 genes, copy number 6: AC027612.3, GGT8P.
- chr3:142,580,910–198,123,232, 944 genes, copy number 6–7 (broad region; genes not listed).
- chr4:4,117,925–4,127,569, 2 genes, copy number 6: AC116562.1, OR7E103P.
- chr5:154,818,492–154,859,252, 1 gene, copy number 5 (within-gene range 3–5): FAXDC2.
- chr5:154,857,553–162,162,977, 105 genes, copy number 5–6 (broad region; genes not listed).
- chr5:162,477,891–162,762,313, 2 genes, copy number 6: RNU6-164P, ARL2BPP5.
- chr5:167,284,799–168,264,157, 1 gene, copy number 5 (within-gene range 4–5): TENM2.
- chr5:167,721,363–168,667,761, 16 genes, copy number 5 (within-gene range 4–5): AC008708.1, AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2, CTB-178M22.2, WWC1, RARS1, FBLL1, PANK3, SLC2A3P1, MIR103A1, MIR103B1, RPL10P9, AC011365.1.
- chr5:170,232,447–173,484,584, 70 genes, copy number 5–7 (broad region; genes not listed).
- chr5:173,973,779–174,850,725, 15 genes, copy number 5 (within-gene range 3–5): C5orf47, RPL12P22, NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2, AC113346.2, MIR4634.
- chr14:36,213,200–36,235,608, 2 genes, copy number 5: AL162511.1, RN7SKP21.
- chr17:59,847,438–59,892,945, 2 genes, copy number 12 (within-gene range 4–12): RNU6-450P, TUBD1.
- chr22:18,178,038–18,345,899, 2 genes, copy number 10: FAM230D, GGTLC5P.
- chr22:18,400,407–18,530,573, 8 genes, copy number 13: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.
- chr22:18,650,023–18,757,906, 3 genes, copy number 7–21: PPP1R26P2, PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 577. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
